Somatic mutation profile of tumor specimen TCGA-G3-AAV1-01A (aliquot TCGA-G3-AAV1-01A-11D-A382-10) from TCGA case TCGA-G3-AAV1, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 51.9 years (18,973 days).
Specimen TCGA-G3-AAV1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 148afa05-dcc5-42f1-87c9-c68df36519b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-AAV1-10A (Blood Derived Normal), aliquot TCGA-G3-AAV1-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e77fe7a5-c0fd-4272-b10e-c9c2ceab32b7

The open-access MAF lists 60 somatic variants for this specimen: 43 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 14, Frame Shift Del 4, Intron 2, Nonsense Mutation 2, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 79/242 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRA1 | c.92G>A p.C31Y | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV101192773; called by muse, mutect2, varscan2
- ANGPTL8 | c.209A>G p.Y70C | Missense Mutation (SNP) | VAF 69/128 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV99370875; called by muse, mutect2, varscan2
- APLNR | c.339G>A p.M113I | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99951279; called by muse, mutect2, varscan2
- ATF3 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.391); catalogued as COSV100421970; called by muse, mutect2, varscan2
- CACNA2D2 | c.2585G>A p.R862H (on ENST00000479441 / NM_001174051.3; = p.R855H on NM_006030.4) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs771678835, COSV99817044; called by muse, mutect2, varscan2
- CCDC171 | c.2912C>A p.S971* | Nonsense Mutation (SNP) | VAF 21/38 reads (55%) | catalogued as COSV99899992; called by muse, mutect2, varscan2
- CD5 | c.1434G>T p.Q478H | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV100075086; called by muse, mutect2
- DCAF7 | c.605G>T p.R202L | Missense Mutation (SNP) | VAF 93/168 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100177573; called by muse, mutect2, varscan2
- DDX39B | c.863A>G p.N288S | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs745700709, COSV100795168, COSV63331533; called by muse, mutect2, varscan2
- DISP1 | c.11G>A p.S4N | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); catalogued as rs1226758143, COSV99450203; called by muse, mutect2
- DNAH7 | c.3428G>T p.W1143L | Missense Mutation (SNP) | VAF 75/190 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100414169; called by muse, mutect2, varscan2
- EVC2 | c.2568T>A p.H856Q | Missense Mutation (SNP) | VAF 77/147 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs745525669, COSV100185267; called by muse, mutect2, varscan2
- FANCC | c.112G>T p.V38L | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100002114, COSV56668025; called by muse, mutect2, varscan2
- GABRA1 | c.704G>C p.G235A | Missense Mutation (SNP) | VAF 64/105 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99195735; called by muse, mutect2, varscan2
- GABRA5 | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59483243; called by muse, mutect2, varscan2
- GIPC1 | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.245); catalogued as rs758287191, COSV100600018; called by muse, mutect2, varscan2
- GUCY1A2 | c.74A>T p.E25V | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as COSV99973318; called by muse, mutect2, varscan2
- IFT122 | c.3696C>G p.C1232W (on ENST00000348417 / NM_052989.3; = p.C1173W on NM_018262.4) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99958846; called by muse, mutect2, varscan2
- INTS2 | c.2221C>T p.R741W | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs201173583, COSV52156621; called by muse, mutect2, varscan2
- KANK1 | c.3554A>G p.D1185G | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.139); catalogued as rs1278099765, COSV101206842; called by muse, mutect2, varscan2
- KCNQ2 | c.1588G>T p.E530* (on ENST00000359125 / NM_172107.4; = p.E502* on NM_004518.6) | Nonsense Mutation (SNP) | VAF 92/195 reads (47%) | catalogued as COSV100609910, COSV60548695; called by muse, mutect2, varscan2
- MCF2L | c.1612del p.Q538Rfs*17 (on ENST00000375608; = p.Q506Rfs*17 on NM_024979.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 150/435 reads (34%) | catalogued as COSV100982549; called by mutect2, pindel, varscan2
- MRPL35 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 160/403 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as COSV99607867; called by muse, mutect2, varscan2
- MYOM1 | c.3692G>A p.R1231H | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs756213299, COSV99865652; called by muse, mutect2, varscan2
- MYOM3 | c.3878T>C p.L1293P | Missense Mutation (SNP) | VAF 43/53 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1240062031, COSV100141581; called by muse, mutect2, varscan2
- NASP | c.1759C>T p.H587Y | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.488); catalogued as COSV100601663; called by muse, mutect2, varscan2
- NOVA1 | c.290A>T p.E97V | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99946722; called by muse, mutect2, varscan2
- PCDHA7 | c.1750T>G p.S584A | Missense Mutation (SNP) | VAF 96/169 reads (57%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.03); catalogued as COSV100971282; called by muse, varscan2
- PLRG1 | c.1522A>C p.I508L | Missense Mutation (SNP) | VAF 86/196 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100122999; called by muse, mutect2, varscan2
- REM2 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1412604370, COSV99944571; called by muse, mutect2, varscan2
- RTKN | c.565T>C p.F189L (on ENST00000272430 / NM_001015055.2; = p.F176L on NM_033046.2) | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51966359, COSV99269386; called by muse, mutect2, varscan2
- SF3B1 | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.745); catalogued as COSV100133980; called by muse, mutect2, varscan2
- TAS2R39 | c.251T>C p.I84T | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.83); catalogued as rs1164912285, COSV101489395; called by muse, mutect2, varscan2
- TIGD7 | c.1109A>G p.K370R | Missense Mutation (SNP) | VAF 8/216 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV99239757; called by muse, mutect2
- TMEM26 | c.751A>C p.S251R | Missense Mutation (SNP) | VAF 114/244 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99515475; called by muse, mutect2, varscan2
- TUBB1 | c.42C>A p.N14K | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.853); catalogued as COSV99413942; called by muse, mutect2, varscan2
- VCAM1 | c.1051A>G p.I351V | Missense Mutation (SNP) | VAF 70/189 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as COSV99658268, COSV99658594; called by muse, mutect2, varscan2
- ZNF831 | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 132/244 reads (54%) | SIFT tolerated (0.55); PolyPhen benign (0.024); catalogued as COSV100925848; called by muse, mutect2, varscan2
- FAM221B | c.807del p.R270Dfs*8 | Frame Shift Del (DEL) | VAF 61/125 reads (49%) | called by mutect2, varscan2
- FZD4 | c.247dup p.T83Nfs*47 | Frame Shift Ins (INS) | VAF 24/114 reads (21%) | called by mutect2, pindel, varscan2
- LMTK2 | c.3033_3038delinsA p.D1011Efs*14 | Frame Shift Del (DEL) | VAF 27/76 reads (36%) | called by pindel, varscan2*
- MUC5B | c.16483_16499del p.P5495Afs*74 | Frame Shift Del (DEL) | VAF 52/128 reads (41%) | called by pindel, varscan2
- ABCA12 | c.4365C>T p.L1455= (on ENST00000272895 / NM_173076.3; = p.L1137= on NM_015657.3) | Silent (SNP) | VAF 53/123 reads (43%) | catalogued as rs1257104572, COSV99788731; called by muse, mutect2, varscan2
- CADPS | c.925C>A p.R309= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as rs1383043582, COSV51889357, COSV99336394; called by muse, mutect2, varscan2
- CCDC171 | c.2913G>C p.S971= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV99899995; called by muse, mutect2, varscan2
- CCDC18 | c.246A>G p.E82= | Silent (SNP) | VAF 46/113 reads (41%) | catalogued as COSV100159300; called by muse, mutect2, varscan2
- CHRNA7 | c.972G>A p.G324= | Silent (SNP) | VAF 211/404 reads (52%) | catalogued as COSV100180976; called by muse, mutect2, varscan2
- EPHA3 | c.495C>T p.N165= | Silent (SNP) | VAF 43/102 reads (42%) | catalogued as COSV100343537; called by muse, mutect2, varscan2
- EXPH5 | c.4230T>G p.S1410= | Silent (SNP) | VAF 47/104 reads (45%) | catalogued as COSV99761104; called by muse, mutect2, varscan2
- KATNAL1 | c.693T>C p.P231= | Silent (SNP) | VAF 36/89 reads (40%) | catalogued as COSV101016749; called by muse, mutect2, varscan2
- MEDAG | c.702G>A p.T234= | Silent (SNP) | VAF 73/191 reads (38%) | catalogued as rs375543579, COSV66850005; called by muse, mutect2, varscan2
- PLRG1 | c.1107A>G p.T369= | Silent (SNP) | VAF 62/130 reads (48%) | catalogued as COSV100123001; called by muse, mutect2, varscan2
- RHBDL2 | c.897A>G p.L299= | Silent (SNP) | VAF 38/65 reads (58%) | catalogued as COSV100008337; called by muse, mutect2, varscan2
- SH2D4A | c.354T>A p.S118= | Silent (SNP) | VAF 61/121 reads (50%) | catalogued as COSV99744341; called by muse, mutect2, varscan2
- SPAG17 | c.2829G>A p.E943= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as COSV100308228, COSV60462848; called by muse, mutect2, varscan2
- TMEM175 | c.228A>T p.T76= | Silent (SNP) | VAF 77/165 reads (47%) | catalogued as COSV99297583; called by muse, mutect2, varscan2
- IL36B | c.261+881_261+891del | Intron (DEL) | VAF 32/109 reads (29%) | called by mutect2, pindel, varscan2
- NRG1 | c.502+31240G>A | Intron (SNP) | VAF 18/106 reads (17%) | catalogued as rs192228210, COSV99827873; called by muse, mutect2, varscan2
- OTOF | c.*86G>T | 3'UTR (SNP) | VAF 65/157 reads (41%) | catalogued as COSV99716799; called by muse, mutect2, varscan2
